Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMZ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMZ-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

DIAGNOSIS:

ANTERIOR EXENTERATION (RADICAL CYSTECTOMY, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY) WITH ILEAL CONDUIT AND GASTRIC TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- CARCINOMA IN SITU

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IN SITU (FLAT LESION)

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- HIGH GRADE DYSPLASIA

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IN SITU (FLAT LESION)

ADDITIONAL RIGHT DISTAL URETER (C):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- FOCAL HIGH GRADE DYSPLASIA:

FINAL DIAGNOSIS:

- FOCAL UROTHELIAL CARCINOMA IN SITU (FLAT LESION)

ADDITIONAL LEFT DISTAL URETER (D):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- CARCINOMA IN SITU

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IN SITU (FLAT LESION)

ADDITIONAL RIGHT DISTAL URETER (E):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO HIGH GRADE DYSPLASIA OR MALIGNANCY IDENTIFIED

ADDITIONAL LEFT DISTAL URETER (F):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

APICAL URETHRAL MARGIN (G):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- CARCINOMA IN SITU

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA IN SITU (FLAT LESION)

BLADDER, CERVIX, UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES (H):

BLADDER:

- EXTENSIVE AND MULTIFOCAL UROTHELIAL CARCINOMA IN SITU (FLAT LESION) AND BOTH NON-INVASIVE AND INVASIVE POORLY DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMAS, GRADE 4/4, EXTENDING THROUGH BLADDER WALL INTO PERIVESICAL SOFT TISSUE
- NO MALIGNANCY IDENTIFIED IN TWO INCIDENTAL RIGHT PERIVESICAL LYMPH NODES EXAMINED (0/2)
- MULTIPLE FOCI OF LYMPHOVASCULAR INVASION IDENTIFIED
- SOFT TISSUE RESECTION MARGINS, FREE OF MALIGNANCY

ICD O-3

Carcinoma, urothelial papillary

8/30/13

Site: Bladder NOS

C679

JW 8/26/14

[page 2 of 8]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

CERVIX:

- NABOTHIAN CYST
- BENIGN SQUAMOUS AND ENDOCERVICAL MUCOSA EXHIBITING NO DYSPLASIA OR MALIGNANCY

UTERUS:

- ENDOMETRIUM, BENIGN ENDOMETRIAL POLYP AND CYSTIC ATROPHY
- MYOMETRIUM, BENIGN INTRAMURAL LEIOMYOMA (1.0 CM DIAMETER)
- SEROSA, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- NO ATYPIA OR MALIGNANCY IDENTIFIED

BILATERAL FALLOPIAN TUBES AND OVARIES:

- RIGHT FALLOPIAN TUBE, WALTHARD REST
- LEFT FALLOPIAN TUBE, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- RIGHT OVARY, ATROPHY AND PHYSIOLOGIC CHANGES
- LEFT OVARY, SIMPLE SEROUS CYST
- NO ATYPIA OR MALIGNANCY IDENTIFIED

URETHRA (I):

- EXTENSIVE UROTHELIAL CARCINOMA IN SITU (FLAT LESION) FOCALLY EXTENDING TO MEATUS, AND NON-INVASIVE POORLY DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMAS, GRADE 4/4
- INKED RESECTION MARGINS, FREE OF DYSPLASIA AND MALIGNANCY

RIGHT PROXIMAL URETER (J):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (K):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PARA AORTIC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

RIGHT PARACAVAL LYMPH NODES (M):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF FOUR LYMPH NODES (1/4)

RIGHT COMMON ILIAC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT COMMON ILIAC LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT EXTERNAL ILIAC LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT LYMPH NODE OF CLOQUET (Q):

- NO LYMPH NODES OR MALIGNANCY IDENTIFIED (0/0) [TOTALLY EMBEDDED]

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (R):

- METASTATIC CARCINOMA IDENTIFIED IN TWO OF 14 LYMPH NODES EXAMINED (2/14)

LEFT EXTERNAL ILIAC LYMPH NODES (S):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT LYMPH NODE OF CLOQUET (T):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

[page 3 of 8]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (U):

- NO MALIGNANCY IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

RIGHT PRESACRAL LYMPH NODE (V):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

PRESACRAL LYMPH NODES (W):

- METASTATIC CARCINOMA IDENTIFIED IN TWO OF SIX LYMPH NODES EXAMINED (2/6)

LEFT PRESACRAL LYMPH NODES (X):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN TOTAL OF 5 OF 69
LYMPH NODES EXAMINED (5/69)

PATHOLOGIC TNM STAGE: BLADDER : pTis,T3aN2MX

URETHRA: pTis,Ta

Electronically signed by
Verified:

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay, results of which will be issued in an addendum.

SPECIMEN SOURCE:

- A: "Right distal ureter"
- B: "Left distal ureter"
- C: "Add'l right distal ureter"
- D: "Add'l left distal ureter"
- E: "Add'l rt distal ureter"
- F: "Add'l Lt. distal ureter"
- G: "Apical urethral margin"
- H: "Bladder, cervix, uterus, bilateral fallopian tubes and o
- I: "Urethra"
- J: "Right proximal ureter"
- K: "Left proximal ureter"
- L: "Left para aortic L.N."
- M: "Right para caval L.N."
- N: "Right common iliac L.N."
- O: "Left common iliac L.N."
- P: "Right external iliac lymph node"
- Q: "Right lymph node of cloquet"
- R: "Right obturator/hypogastric lymph nodes"
- S: "Left external iliac L.N."
- T: "Left L.N. of cloquet"
- U: "Left obturator hypogastric L.N."
- V: "Right pre sciatic L.N."
- W: "Pre sacral L.N."
- X: "Left pre sciatic L.N."

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer

Post-op Dx: Same

GROSS EXAMINATION:

[page 4 of 8]
Collected

Ordered by

Location

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter". It consists of a portion of distal ureter measuring 0.4 cm in length x 0.9 cm in diameter. The specimen is entirely submitted in one cassette for frozen section in AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter". It consists of a portion of adipose tissue measuring 1.5 x 1 x 0.5 with an embedded ureter which measures 0.4 cm in length x 0.3 cm in diameter. The specimen is entirely submitted in one cassette for frozen section in BFS.

C: The specimen is received fresh from the O.R. and labeled "Add'l right distal ureter". It consists of a portion of the ureter measuring 1.5 cm in length x 0.9 cm in diameter with a suture at the distal end for specimen orientation. The proximal margin is submitted for frozen section in a single cassette (CFS) with the remaining tissue submitted in C1 for routine processing.

D: The specimen is received fresh from the O.R. and labeled "Add'l left distal ureter". It consists of a portion of oriented ureter measuring 1.4 cm in length x 0.4 cm in diameter with two metal clips representing the distal end of the specimen. A representative section from the proximal margin of the ureter is submitted for frozen section in DFS and the remaining tissue is submitted for routine processing in D1.

E: The specimen is received fresh from the O.R. and labeled "Add'l rt distal ureter". It consists of an oriented portion of ureter measuring 1.1 cm in length x 0.9 cm in diameter with a suture at the distal end. A representative section is taken from the proximal margin for frozen section diagnosis in EFS. Remaining tissue is submitted in E1 for routine processing.

F: The specimen is received fresh from the O.R. and labeled "Add'l Lt. distal ureter". It consists of a portion of ureter measuring 1.0 cm in length x 0.4 cm in diameter with two clips at the distal end. A representative section is taken from the proximal margin for frozen section diagnosis in FFS. Remaining tissue is submitted in F1 for routine processing.

G: The specimen is received fresh from the O.R. and labeled "Apical urethral margin". It consists of two pieces of tissue measuring 1.1 x 0.4 x 0.5 cm and 0.6 x 0.6 x 0.3 cm. The specimen is entirely submitted in one cassette for frozen section diagnosis in GFS.

H: The specimen is received fresh from the O.R. and labeled "Bladder, cervix, uterus, bilateral fallopian tubes and ovaries". It consists of an anterior exenteration specimen measuring overall 25 x 18.5 x 5 cm and includes the bladder, cervix, uterus and bilateral fallopian tube and ovaries. A flap of peritoneal fat is present measuring 23 x 13 x 0.1 cm. It is smooth and glistening. The bladder margins are inked black and the bladder is opened from the anterior side. The bladder itself measures 7 x 5.5 x 3.5 cm. The uninvolved bladder wall measures 0.9 cm in thickness. The entire mucosa is plastered with multiple variably sized dome shaped friable lesions measuring between 0.2 and 2 cm in greatest diameter. The mucosa between these lesions is lush and velvety. The right ureterovesical junction is identified and the attached right ureter is opened. It measures 5.5 cm in length x 1 cm in circumference. A fungating mass obstructing the inlet is present in the intramural portion of the ureter and measures 1.7 x 0.6 x 0.5 cm. The left ureterovesical junction is identified and the left attached ureter is opened. It measures 4 cm in length with a circumference ranging from 0.3 up to 0.6 cm. Adjacent to the left ureterovesical junction is a fungating mass measuring 1.2 x 0.8 x 0.7 cm. This lesion does not appear to obstruct the outflow from the left ureter. The uterus with cervix measures 7 x 3.5 x 3 cm. The serosal surface is light tan, glistening and grossly unremarkable. The cervix measures 2 cm in diameter and is covered by light tan smooth mucosa. The cervical os is round and

[page 5 of 8]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

measures 0.2 cm. The endocervical canal measures 1 cm in length x 0.6 cm in diameter. The endometrial cavity measures 3.5 x 2 cm. A 3.5 x 1.7 x 0.7 cm polyp is present in the cavity. The myometrium thickness averages 0.5 cm. A 1 cm in diameter firm light tan nodule is located in the posterior fundus and appears grossly arising from the myometrium. The left ovary measures 2 x 1 x 0.6 cm and the attached fallopian tube measures 8 cm in length with a diameter averaging between 0.3 and 0.5 cm. The right ovary measures 2.5 x 2.3 x 1.2 cm. The right fallopian tube measures 8 cm in length with a diameter averaging between 0.2 and 0.5 cm. The sectioned right ovary is grossly unremarkable. The sectioned left ovary is 80% replaced by a cyst filled with light thin yellow fluid. The cyst is unilocular and has a smooth inner surface. Its wall averages 0.2 cm in thickness. Representative sections are submitted in 25 cassettes.

I: The specimen is received fresh from the O.R. and labeled "Urethra". It consists of A urethra measuring 2.6 cm in length x 1.6 cm in diameter. The external margins are inked black and blue is superimposed on the distal (meatal) end. Representative sections are submitted in three cassettes.

J: The specimen is received fresh from the O.R. and labeled "Right proximal ureter". It consists of an oriented portion of ureter measuring 1 cm in length x 0.6 cm in diameter. The final proximal margin is submitted in J1 with the remaining tissue submitted in J2.

K: The specimen is received fresh from the O.R. and labeled "Left proximal ureter". It consists of an oriented portion of ureter measuring 1 cm in length x 0.3 cm in diameter. The final proximal margin is submitted in K1 with the remaining tissue submitted in K2.

L: The specimen is received in formalin and labeled "Left para aortic L.N.". It consists of one segment of adipose tissue measuring 2.5 x 1.6 x 0.8 cm. The specimen is entirely submitted in two cassettes.

M: The specimen is received in formalin and labeled "Right para caval L.N.". It consists of one segment of adipose tissue measuring 2.6 x 1.4 x 0.7 cm. The specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Right common iliac L.N.". It consists of multiple pieces of adipose tissue measuring in aggregate 2.8 x 3 x 0.7 cm. The specimen is entirely submitted in four cassettes.

O: The specimen is received in formalin and labeled "Left common iliac L.N.". It consists of multiple pieces of tissue measuring 2.4 x 2 x 1.2 cm. The specimen is entirely submitted in two cassettes.

P: The specimen is received in formalin and labeled "Right external iliac lymph node". It consists of multiple pieces of adipose tissue measuring 3.8 x 3 x 1.7 cm. The specimen is entirely submitted in four cassettes.

Q: The specimen is received in formalin and labeled "Right lymph node of cloquet". It consists of one fragment of adipose tissue measuring 0.8 x 0.6 x 0.2 cm. The specimen is entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "Right obturator/hypogastric lymph nodes". It consists of multiple pieces of adipose tissue measuring in aggregate 5.2 x 4.2 x 1.7 cm. The specimen is entirely submitted in five cassettes.

S: The specimen is received in formalin and labeled "Left external iliac L.N.". It consists of multiple fragments of adipose tissue measuring in aggregate 4.5 x 2.6 x 0.7 cm. The specimen is entirely submitted in five cassettes.

[page 6 of 8]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

T: The specimen is received in formalin and labeled "Left L.N. of cloquet". It consists of one fragment of adipose tissue measuring 0.8 x 0.5 x 0.4 cm. The specimen is entirely submitted in one cassette.

U: The specimen is received in formalin and labeled "Left obturator hypogastric L.N.". It consists of multiple pieces of adipose tissue measuring in aggregate 3.4 x 3 x 1.4 cm. The specimen is entirely submitted in four cassettes.

V: The specimen is received in formalin and labeled "Right pre sciatic L.N.". It consists of multiple fragments of adipose tissue measuring in aggregate 2.8 x 2.2 x 1.4 cm. The specimen is entirely submitted in two cassettes.

W: The specimen is received in formalin and labeled "Pre sacral L.N.". It consists of multiple fragments of fibroconnective tissue measuring in aggregate 2.5 x 1.2 x 0.7 cm. The specimen is entirely submitted in two cassettes.

X: The specimen is received in formalin and labeled "Left pre sciatic L.N.". It consists of multiple fragments of adipose tissue measuring in aggregate 1.7 x 1.2 x 0.7 cm. The specimen is entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, additional right distal ureter
C1: remaining tissue
DFS: frozen section, representative sections from the proximal portion of the ureter
D1: remaining tissue
EFS: frozen section, additional distal ureter
E1: remaining tissue
FFS: frozen section, additional left distal ureter
F1: remaining tissue
GFS: frozen section, apical urethral margin
H1: bladder, cervix, uterus, bilateral fallopian tube and ovaries; anterior bladder wall
H2: right lateral bladder wall
H3-4: right lateral wall
H5: right ureterovesical junction
H6-7: dome of bladder
H8: posterior bladder wall
H9: left lateral bladder wall
H10: left ureterovesical junction
H11: left ureter
H12: left perivesical soft tissue
H13: trigone and bladder neck
H14: right perivesical soft tissue (possible lymph nodes)
H15: left perivesical soft tissue (possible lymph nodes)
H16: right ovary and tube
H17: left ovary and tube
H18: possible leiomyoma
H19: anterior cervix
H20: posterior cervix
H21: above described endometrial polyp
H22-23: anterior myometrium and serosa
H24-25: posterior myometrium and serosa
I1-3: urethra
J1: right proximal ureter margin
J2: remaining ureter
K1: left proximal ureter margin

[page 7 of 8]
Collected:
Ordered by:

Location:

K2: remaining ureter
L1,2: left para aortic lymph node
M: right para caval lymph node
N1-4: right common iliac lymph node
O1,2: left common iliac lymph node
P1-4: right external iliac lymph node
Q: right lymph node of Cloquet
R1-5: right obturator/hypogastric lymph node
S1-5: left external iliac lymph node
T: left lymph node of Cloquet
U1-4: left obturator hypogastric lymph node
V1,2: right pre sciatic lymph node
W1,2: pre sacral lymph node
X: left pre sciatic lymph node

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter
- carcinoma in-situ

BFS: Left distal ureter
- high grade dysplasia

CFS: Additional right distal ureter
- focal high grade dysplasia

DFS: Additional left distal ureter
- carcinoma in-situ

EFS: Additional right distal ureter
- no high grade atypia or tumor identified

FFS: Additional left distal ureter
- no high grade atypia or tumor identified

GFS: Apical urethral margin
- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-G: See final microscopic-diagnosis.

H: Sections of the bladder show multifocal urothelial carcinoma in situ (flat lesion) [H1-4,6-10] and both non-invasive and invasive poorly differentiated papillary urothelial carcinomas (H2-7,10), grade 4/4. Invasive carcinoma extends through the entire bladder wall into perivesical soft tissue where it is associated with multiple foci of lymphovascular invasion (H5). Two incidental right perivesical lymph nodes are identified both of which are free of malignancy (O/2). Soft tissue resection margins are free of malignancy. Final resection margins of both right and left ureters are free of both urothelial dysplasia and malignancy (EFS, FFS, J, K). Urothelial carcinoma in situ involves the initial apical urethral margin (GFS), and along with non-invasive papillary carcinoma, is also noted to involve the urethra (I) where it focally extends to the meatus.

I-X: See final microscopic-diagnosis.

[page 8 of 8]
Collected:	
Ordered by:	
	Location:

Source: NCI Genomic Data Commons file 87e3914e-f9fd-452a-b23c-f228c03cf6d0 (TCGA-XF-AAMZ.45680E92-721E-4332-9E45-7F134D7AFCAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).